Somatic mutation profile of tumor specimen TCGA-BQ-7051-01A (aliquot TCGA-BQ-7051-01A-12D-1961-08) from TCGA case TCGA-BQ-7051, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 74.3 years (27,120 days).
Specimen TCGA-BQ-7051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ebc4bd6-733f-4520-a94a-88fe98dfdc7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7051-11A (Solid Tissue Normal), aliquot TCGA-BQ-7051-11A-02D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35425fed-1755-441f-9084-7fc751ca9ae2

The open-access MAF lists 98 somatic variants for this specimen: 70 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 27, Frame Shift Del 10, Nonsense Mutation 3, Splice Region 2, Intron 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- ARHGAP36 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 76/84 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52269736; called by muse, mutect2, varscan2
- ARMC10 | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as rs1272826012, COSV60392937; called by muse, mutect2, varscan2
- C1QTNF6 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55396994; called by muse, mutect2, varscan2
- CCNT1 | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV56065526; called by muse, mutect2, varscan2
- CEP350 | c.3631A>C p.K1211Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV62607063; called by muse, mutect2, varscan2
- CIP2A | c.1589G>T p.R530I | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs760405840, COSV55418397, COSV55420277; called by muse, mutect2, varscan2
- CNTN1 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV61643040; called by muse, mutect2, varscan2
- COL1A1 | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV56807909; called by muse, mutect2, varscan2
- COX5A | c.213del p.I74* | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | catalogued as COSV59280094; called by mutect2, pindel, varscan2
- CRTC1 | c.918C>G p.H306Q | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV58721428; called by muse, mutect2, varscan2
- CTNNA1 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57073672; called by muse, mutect2, varscan2
- CYP4A11 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as COSV60224736, COSV60225571; called by muse, mutect2, varscan2
- DCLK1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1340568626, COSV55173920; called by muse, mutect2, varscan2
- DHX29 | c.507T>C p.D169= | Splice Region (SNP) | VAF 22/51 reads (43%) | catalogued as COSV52419863; called by muse, mutect2, varscan2
- DNAH11 | c.4851C>A p.Y1617* | Nonsense Mutation (SNP) | VAF 44/167 reads (26%) | catalogued as COSV60969344; called by muse, mutect2, varscan2
- DOCK6 | c.5613G>T p.K1871N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1333720864, COSV53918918; called by muse, varscan2
- DOCK6 | c.5573C>G p.P1858R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.141); catalogued as COSV53918934; called by muse, varscan2
- FREM2 | c.8431T>G p.Y2811D | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845416; called by muse, mutect2, varscan2
- GUCA1B | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50004875; called by muse, mutect2, varscan2
- HSPG2 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV65930611; called by muse, mutect2, varscan2
- KMT2D | c.6354dup p.A2119Rfs*36 | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | catalogued as rs755159728; called by mutect2, pindel, varscan2
- KRT27 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs988877353, COSV56972712; called by muse, mutect2
- KRT80 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57550707; called by muse, mutect2, varscan2
- MAST4 | c.3425T>C p.I1142T (on ENST00000403625 / NM_001164664.2; = p.I953T on NM_015183.3) | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs748456473, COSV55134774; called by muse, mutect2, varscan2
- MSTO1 | c.305C>G p.T102S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV99824285; called by muse, mutect2, varscan2
- MYO3B | c.3494G>A p.R1165H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs372050798; called by muse, mutect2, varscan2
- NLRX1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52707225; called by muse, mutect2, varscan2
- NSUN7 | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57275328; called by muse, mutect2, varscan2
- OR4A16 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as COSV59044464; called by muse, mutect2
- PHF1 | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65703152; called by muse, mutect2, varscan2
- PITRM1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56536234; called by muse, mutect2, varscan2
- PLCH2 | c.3772G>A p.G1258S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53946920; called by muse, mutect2, varscan2
- PLXND1 | c.3341G>C p.C1114S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV60716923; called by muse, mutect2
- PNP | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775032909, COSV64092127; called by muse, mutect2, varscan2
- POLN | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs142911650; called by muse, mutect2, varscan2
- POLR2B | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.078); catalogued as COSV58901852; called by muse, mutect2, varscan2
- POLR2B | c.2967A>G p.V989= | Splice Region (SNP) | VAF 36/83 reads (43%) | catalogued as rs780566944, COSV58901855; called by muse, mutect2, varscan2
- POP1 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV62893709; called by muse, mutect2, varscan2
- PRORP | c.213T>G p.D71E | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51621352; called by muse, mutect2, varscan2
- PTEN | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV64299114, COSV99057991; called by muse, mutect2, varscan2
- RANBP2 | c.2164A>T p.I722L | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746264200, COSV51705442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF31 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777889587, COSV60727776; called by muse, mutect2, varscan2
- RRAGB | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV53330238, COSV53330884; called by muse, mutect2, varscan2
- SACM1L | c.1089A>T p.Q363H | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV66614475; called by muse, mutect2, varscan2
- SFI1 | c.2098G>C p.D700H (on ENST00000400288 / NM_001007467.3; = p.D669H on NM_014775.4) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.366); catalogued as COSV66292050; called by muse, mutect2, varscan2
- SLC22A13 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61291657; called by muse, mutect2, varscan2
- SLC38A3 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68844099; called by muse, mutect2, varscan2
- SLMAP | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV55850843; called by muse, mutect2, varscan2
- SPAG5 | c.2270T>C p.L757P | Missense Mutation (SNP) | VAF 234/343 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58803282; called by muse, mutect2, varscan2
- STXBP2 | c.1564A>T p.N522Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV55404744; called by muse, mutect2, varscan2
- SULT1C4 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV55598474; called by muse, mutect2, varscan2
- UBE4A | c.1639C>T p.Q547* (on ENST00000252108 / NM_001204077.2; = p.Q554* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 47/89 reads (53%) | catalogued as COSV52805990; called by muse, mutect2, varscan2
- USHBP1 | c.1835G>C p.R612P | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as COSV53105156, COSV99394568; called by muse, mutect2, varscan2
- ZGPAT | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779452220, COSV56650522; called by muse, mutect2, varscan2
- ZNF253 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV63038044; called by muse, mutect2, varscan2
- ZNF471 | c.1756T>C p.C586R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57292648; called by muse, mutect2, varscan2
- ZNF514 | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.143); catalogued as COSV54634868; called by muse, mutect2, varscan2
- ZNF721 | c.2201T>G p.I734S (on ENST00000338977; = p.I746S on NM_133474.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV59095263; called by muse, mutect2, varscan2
- ADAMTS20 | c.3431del p.L1144Yfs*7 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, varscan2
- ADAMTS9 | c.4734_4743del p.K1579Vfs*16 | Frame Shift Del (DEL) | VAF 35/131 reads (27%) | called by mutect2, pindel, varscan2
- KBTBD6 | c.1036_1038del p.V346del | In Frame Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- KMT2C | c.5208del p.F1736Lfs*5 | Frame Shift Del (DEL) | VAF 257/498 reads (52%) | called by mutect2, pindel, varscan2
- MATN2 | c.568_571del p.L190Sfs*9 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- MFN2 | c.908_909del p.F303Cfs*4 | Frame Shift Del (DEL) | VAF 23/45 reads (51%) | called by mutect2, pindel, varscan2
- PAK1 | c.1260del p.K420Nfs*6 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- RHOB | c.79_113del p.K27Lfs*9 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel
- SLC46A1 | c.856del p.D286Tfs*3 | Frame Shift Del (DEL) | VAF 60/120 reads (50%) | called by mutect2, pindel, varscan2
- TACSTD2 | c.698_699del p.E233Vfs*143 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- TBC1D3L | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1989T>C p.H663= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV51854012; called by muse, mutect2, varscan2
- ARFGAP3 | c.882T>C p.I294= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as COSV54313420; called by muse, mutect2, varscan2
- C6orf47 | c.300T>C p.T100= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV63263990; called by muse, mutect2, varscan2
- CAND1 | c.1896G>A p.L632= | Silent (SNP) | VAF 62/128 reads (48%) | catalogued as COSV73389615; called by muse, varscan2
- DPPA3 | c.90T>A p.S30= | Silent (SNP) | VAF 84/195 reads (43%) | catalogued as COSV61503360; called by muse, mutect2, varscan2
- DYNLL2 | c.6T>A p.S2= | Silent (SNP) | VAF 54/78 reads (69%) | catalogued as COSV73897053; called by muse, mutect2, varscan2
- FKBP4 | c.708A>G p.Q236= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs201311104, COSV50009571; called by muse, mutect2, varscan2
- HEPH | c.93C>T p.G31= (on ENST00000343002; = p.G85= on NM_138737.5) | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV57961220, COSV57968573; called by muse, mutect2, varscan2
- HEXD | c.162T>C p.P54= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV60065184; called by muse, mutect2, varscan2
- HIVEP3 | c.1884T>A p.L628= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as COSV56019781; called by muse, mutect2, varscan2
- NCOA4 | c.1704A>T p.V568= | Silent (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2, varscan2
- OR7A17 | c.273C>T p.V91= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as COSV59414830; called by muse, mutect2, varscan2
- PPM1M | c.462C>T p.L154= (on ENST00000296487; = p.L315= on NM_144641.4) | Silent (SNP) | VAF 59/126 reads (47%) | catalogued as COSV56599691; called by muse, mutect2, varscan2
- PTPN14 | c.2205C>T p.A735= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV65286282; called by muse, varscan2
- PTPRT | c.1386C>T p.L462= | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as COSV62002548; called by muse, mutect2, varscan2
- RP1 | c.768A>G p.A256= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV55122250; called by muse, mutect2, varscan2
- RPRM | c.81G>A p.V27= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV57989024; called by muse, mutect2, varscan2
- SIN3A | c.3609C>T p.S1203= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as COSV51234756; called by muse, mutect2, varscan2
- SYN1 | c.2073C>G p.T691= | Silent (SNP) | VAF 53/56 reads (95%) | catalogued as COSV51694235; called by muse, mutect2, varscan2
- SYNJ2 | c.432C>T p.V144= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs372960799; called by muse, mutect2, varscan2
- TEP1 | c.6046C>T p.L2016= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV52996717; called by muse, mutect2, varscan2
- TICRR | c.1803T>C p.D601= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV51544617; called by muse, mutect2, varscan2
- TIMM21 | c.279C>G p.T93= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV50054008; called by muse, mutect2, varscan2
- TMCO6 | c.372G>A p.L124= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52800629; called by muse, mutect2, varscan2
- TRIM29 | c.1617C>T p.F539= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs750001339, COSV59281553; called by muse, mutect2, varscan2
- TUT4 | c.4045C>A p.R1349= | Silent (SNP) | VAF 67/148 reads (45%) | catalogued as COSV57117451; called by muse, mutect2, varscan2
- VTI1B | c.660G>A p.L220= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV53620442; called by muse, mutect2, varscan2
- SLC45A4 | c.242-6420C>T | Intron (SNP) | VAF 71/166 reads (43%) | catalogued as rs1312185115, COSV50152939; called by muse, mutect2, varscan2
